TCGA case TCGA-B6-A0RH — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c3148e68-1739-4334-abda-1dcbc2166846

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Dead; Days to death: 6,456 days (17.7 years).

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.4 years (18,759 days); Year of diagnosis: 1991; Method of diagnosis: Incisional Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Lower Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 23; Micrometastasis present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 57.3 years (20,924 days); Days to diagnosis: 2,165 days (5.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Treatment anatomic sites: Locoregional Site.

Follow-up (3 entries)
- Day 2,165 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 2,165 days (5.9 years).
- Days to follow up: 5,749 days (15.7 years); Disease response: Tumor Free.
- Days to follow up: 6,456 days (17.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A0RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-B6-A0RH-01A-02-BSB: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-B6-A0RH-01A-02-TSB: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A0RH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B6-A0RH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Er positivity method: Immunohistochemistry; Pr positivity define method: Immunohistochemistry; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Indeterminate (neither Pre or Postmenopausal); Micromet detection by IHC: No; Margin status reexcision: Negative; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Lower Inner Quadrant.
- Follow-up form 1: Tumor status: Tumor free; New tumor event type: Locoregional Disease; New tumor event site other: Chest Wall; New tumor event surgery: Yes; New tumor event surgery days to met: 2268; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 6,456 days; disease-specific survival: no event (censored), 6,456 days; disease-free interval: event (new tumor event after initially disease-free), 2,165 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,165 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A0RH-01A-21D-A111-01): tumor purity 0.66, ploidy 2.02, whole-genome doublings 0.
